MMRF case MMRF_2453 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/e5e1049b-1566-4683-81e4-af1af5c94605

Demographics
Sex at birth: female; Age at index: 58 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 58.5 years (21,380 days); ISS stage: II; Days to last known disease status: 737 days (2.0 years); Days to last follow up: 737 days (2.0 years).
   Treatment given: Therapeutic agents: Bortezomib + Cyclophosphamide + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 312 days; Days to treatment end: 312 days.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -6 (ECOG 2): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 135 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.98 mg/dL; Beta 2 Microglobulin 5.4 µg/mL; Lactate Dehydrogenase 6.85 µkat/L; Hemoglobin 5.39 mmol/L; Leukocytes 10.5 ×10⁹/L; Absolute Neutrophil 6.4 ×10⁹/L; Platelets 107 ×10⁹/L; Creatinine 210 µmol/L; Blood Urea Nitrogen 9.64 mmol/L; Calcium 2.85 mmol/L; Albumin 38 g/L; Total Protein 5.4 g/dL; Glucose 5.83 mmol/L; C-Reactive Protein 0.173 mg/dL.
- Day 91: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 5.33 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.87 mg/dL; Immunoglobulin G 3.03 g/L; Immunoglobulin A 0.54 g/L; Immunoglobulin M 0.15 g/L; Lactate Dehydrogenase 3.13 µkat/L; Hemoglobin 5.46 mmol/L; Leukocytes 7.2 ×10⁹/L; Absolute Neutrophil 6.1 ×10⁹/L; Platelets 207 ×10⁹/L; Creatinine 77.8 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.15 mmol/L; Albumin 40 g/L; Total Protein 6.1 g/dL; Glucose 5.56 mmol/L.
- Day 179 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.4 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.28 mg/dL; Immunoglobulin G 4.03 g/L; Immunoglobulin A 0.43 g/L; Immunoglobulin M 0.14 g/L; Lactate Dehydrogenase 2.8 µkat/L; Hemoglobin 5.7 mmol/L; Leukocytes 6 ×10⁹/L; Absolute Neutrophil 4 ×10⁹/L; Platelets 379 ×10⁹/L; Creatinine 57.5 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.25 mmol/L; Albumin 42 g/L; Total Protein 6 g/dL; Glucose 5.28 mmol/L.
- Day 273 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.03 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.64 mg/dL; Immunoglobulin G 4.37 g/L; Immunoglobulin A 0.46 g/L; Immunoglobulin M 0.17 g/L; Lactate Dehydrogenase 2.65 µkat/L; Hemoglobin 6.57 mmol/L; Leukocytes 5.5 ×10⁹/L; Absolute Neutrophil 4.1 ×10⁹/L; Platelets 248 ×10⁹/L; Creatinine 64.5 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.33 mmol/L; Albumin 47 g/L; Total Protein 6.6 g/dL; Glucose 6.33 mmol/L.
- Day 354 (ECOG 2): M Protein 0.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.66 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.13 mg/dL; Immunoglobulin G 9.87 g/L; Immunoglobulin A 0.56 g/L; Immunoglobulin M 0.25 g/L; Lactate Dehydrogenase 3.02 µkat/L; Hemoglobin 5.46 mmol/L; Leukocytes 5.4 ×10⁹/L; Absolute Neutrophil 2.3 ×10⁹/L; Platelets 237 ×10⁹/L; Creatinine 59.2 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.23 mmol/L; Albumin 37 g/L; Total Protein 5.9 g/dL; Glucose 3.96 mmol/L.
- Day 457 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.52 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.03 mg/dL; Immunoglobulin G 8.91 g/L; Immunoglobulin A 0.8 g/L; Immunoglobulin M 0.28 g/L; Lactate Dehydrogenase 2.25 µkat/L; Hemoglobin 6.45 mmol/L; Leukocytes 4.9 ×10⁹/L; Absolute Neutrophil 2.4 ×10⁹/L; Platelets 185 ×10⁹/L; Creatinine 84 µmol/L; Blood Urea Nitrogen 8.21 mmol/L; Calcium 2.3 mmol/L; Albumin 40 g/L; Total Protein 6.3 g/dL; Glucose 4.51 mmol/L.
- Day 549 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.61 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.96 mg/dL; Immunoglobulin G 9.87 g/L; Immunoglobulin A 0.95 g/L; Immunoglobulin M 0.3 g/L; Lactate Dehydrogenase 2.17 µkat/L; Hemoglobin 6.94 mmol/L; Leukocytes 5.8 ×10⁹/L; Absolute Neutrophil 3.1 ×10⁹/L; Platelets 159 ×10⁹/L; Creatinine 71.6 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 2.33 mmol/L; Albumin 43 g/L; Total Protein 6.6 g/dL; Glucose 5.06 mmol/L.
- Day 639 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.29 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.92 mg/dL; Immunoglobulin G 9.57 g/L; Immunoglobulin A 1.27 g/L; Immunoglobulin M 0.3 g/L; Lactate Dehydrogenase 2.03 µkat/L; Hemoglobin 7.5 mmol/L; Leukocytes 2.8 ×10⁹/L; Absolute Neutrophil 1.6 ×10⁹/L; Platelets 142 ×10⁹/L; Creatinine 69.8 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.43 mmol/L; Albumin 42 g/L; Total Protein 6.8 g/dL; Glucose 5.78 mmol/L.
- Day 737 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.76 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.78 mg/dL; Immunoglobulin G 12 g/L; Immunoglobulin A 1.43 g/L; Immunoglobulin M 0.35 g/L; Lactate Dehydrogenase 2.55 µkat/L; Hemoglobin 7.44 mmol/L; Leukocytes 3.1 ×10⁹/L; Absolute Neutrophil 1.4 ×10⁹/L; Platelets 97 ×10⁹/L; Creatinine 75.1 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.35 mmol/L; Albumin 41 g/L; Total Protein 7.5 g/dL; Glucose 5.72 mmol/L.

Other clinical attributes
- Day -6: Weight: 48 kg; Height: 173 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_2453_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -6 days.
- Sample MMRF_2453_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -6 days.
